MMRF case MMRF_2621 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/dd289ca0-d992-46af-b22b-22e4464f0a7d

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Dead; Days to death: 201 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.2 years (19,071 days); ISS stage: III; Days to last known disease status: 201 days; Days to last follow up: 201 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 133 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 201.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 1): M Protein 2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 127 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 23.9 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 8.6 µg/mL; Lactate Dehydrogenase 5.72 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.86 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 3.35 mmol/L; Albumin 36 g/L; Total Protein 8.4 g/dL; Glucose 5.94 mmol/L.
- Day 63 (ECOG 2): M Protein 0.13 g/dL; Hemoglobin 5.89 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 42 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.05 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 6.33 mmol/L.
- Day 189 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 166 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0 mg/dL; Immunoglobulin G 2.3 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 9.95 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 201 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -1: Weight: 76 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Melanoma; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship sex at birth: male.

Biospecimens (3 samples)
- Sample MMRF_2621_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_2621_1_PB_CD138pos: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
- Sample MMRF_2621_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
